Somatic mutation profile of tumor specimen C3N-03916-03 (aliquot CPT0222550006) from CPTAC case C3N-03916, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.5 years (27,214 days).
Specimen C3N-03916-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d16d3801-1338-49de-af2f-1854143b6b21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03916-71 (Blood Derived Normal), aliquot CPT0222650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59197e2d-532c-4148-b986-947093bb4db7

The open-access MAF lists 636 somatic variants for this specimen: 392 protein-altering or splice-affecting, 220 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 353, Silent 220, Nonsense Mutation 32, Intron 16, Frame Shift Ins 3, Splice Region 3, 3'UTR 3, 5'Flank 2, 5'UTR 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 108/464 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.4249G>T p.D1417Y (on ENST00000372530 / NM_001198934.2; = p.D1389Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/870 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55086014; called by muse, mutect2, varscan2
- ABL2 | c.3391C>T p.R1131C (on ENST00000502732 / NM_007314.4; = p.R1116C on NM_005158.5) | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1000903902; called by muse, mutect2, varscan2
- AC100868.1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 116/539 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV51849811, COSV51851501; called by muse, mutect2, varscan2
- AC100868.1 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV51837927, COSV99225432; called by muse, mutect2, varscan2
- ACAP1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 152/603 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as rs374720398; called by muse, mutect2, varscan2
- ACSL5 | c.1048G>C p.A350P (on ENST00000354273; = p.A406P on NM_016234.3) | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100634513, COSV61133283; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs775081249, COSV54643616; called by muse, mutect2, varscan2
- ADAD2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 193/846 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.079); catalogued as rs375713849; called by muse, mutect2, varscan2
- ADAMTS16 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99943466; called by muse, mutect2, varscan2
- ADAMTS19 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); catalogued as rs1287635410; called by muse, mutect2, varscan2
- ADGRA3 | c.1573C>G p.R525G | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs200043303; called by muse, mutect2, varscan2
- ADGRG2 | c.256G>A p.E86K (on ENST00000379869 / NM_001079858.3; = p.E83K on NM_005756.4) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756209879; called by muse, mutect2, varscan2
- AGAP3 | c.974C>T p.P325L (on ENST00000622464; = p.P361L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 770/1166 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs772763986, COSV100103707; called by muse, varscan2
- AIPL1 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 202/793 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as rs1241141763; called by muse, mutect2, varscan2
- AKAP6 | c.6232G>A p.E2078K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1180001829; called by muse, varscan2
- AMER2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 222/737 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1566015400, COSV104416942; called by muse, mutect2, varscan2
- ARID2 | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV57595985; called by muse, mutect2, varscan2
- ARID2 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 39/121 reads (32%) | catalogued as COSV57596882; called by muse, mutect2, varscan2
- ASTN2 | c.1683G>A p.W561* (on ENST00000313400 / NM_001365069.1; = p.W510* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 48/223 reads (22%) | catalogued as COSV57774684; called by muse, mutect2, varscan2
- ATF7IP | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); catalogued as COSV53770483; called by muse, mutect2, varscan2
- ATP1A2 | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775974337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 107/520 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as rs751842287, COSV54892072; called by muse, mutect2, varscan2
- C1QTNF1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 208/781 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs542360197, COSV100189693; called by muse, mutect2, varscan2
- C1orf127 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 174/723 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1204405318; called by muse, mutect2, varscan2
- C2CD3 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs143645446; called by muse, mutect2, varscan2
- C2orf16 | c.2902G>A p.G968S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.271); catalogued as COSV100821113; called by muse, mutect2, varscan2
- C6orf58 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100315056; called by muse, varscan2
- C9 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs867203884, COSV54678843; called by muse, mutect2, varscan2
- C9orf72 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs372541138; called by muse, mutect2, varscan2
- CALD1 | c.1717G>A p.E573K (on ENST00000361675 / NM_033138.4; = p.E318K on NM_004342.7) | Missense Mutation (SNP) | VAF 572/865 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774133569; called by muse, mutect2, varscan2
- CARF | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.292); catalogued as rs745904615, COSV57549905; called by muse, mutect2, varscan2
- CAVIN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV58423225; called by muse, mutect2, varscan2
- CCDC181 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs773563534, COSV63156807; called by muse, mutect2, varscan2
- CCER1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 172/735 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1405925733, COSV62646901; called by muse, mutect2, varscan2
- CDC42BPG | c.3575C>T p.T1192I | Missense Mutation (SNP) | VAF 151/665 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs767403805; called by muse, mutect2, varscan2
- CDCP1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 153/633 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs747034363; called by muse, mutect2, varscan2
- CDH22 | c.1728C>G p.F576L | Missense Mutation (SNP) | VAF 147/666 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV64837273; called by muse, mutect2, varscan2
- CDHR2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 139/591 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs565382865; called by muse, mutect2, varscan2
- CENPC | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 90/421 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs200888615; called by muse, mutect2
- CHDH | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 143/622 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1365372126; called by muse, mutect2, varscan2
- CHRDL1 | c.896G>A p.R299Q (on ENST00000372045; = p.R305Q on NM_145234.4) | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1037358691, COSV54323495; called by muse, mutect2, varscan2
- CNTN5 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV54301000; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by muse, mutect2, varscan2
- COL19A1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1190440161, COSV59570468, COSV59577886; called by muse, mutect2, varscan2
- COL20A1 | c.1125C>A p.D375E | Missense Mutation (SNP) | VAF 144/678 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.22); catalogued as COSV58918927; called by muse, mutect2
- COL4A5 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.572); catalogued as COSV60370845; called by muse, mutect2, varscan2
- CTBP1 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 264/644 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.073); catalogued as rs1356384820, COSV52071598; called by muse, mutect2, varscan2
- CYFIP2 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 83/371 reads (22%) | catalogued as rs868243549, COSV59030613, COSV59050697; called by muse, mutect2, varscan2
- CYP2C18 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53669788, COSV99608889; called by muse, mutect2, varscan2
- CYP3A43 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541842153, COSV99733809; called by muse, mutect2, varscan2
- DAPP1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs1383892303, COSV56451030; called by muse, mutect2, varscan2
- DISP3 | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs1201071534, COSV53820589; called by muse, mutect2, varscan2
- DLL3 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 240/979 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs765398793; called by muse, mutect2, varscan2
- DNAH10 | c.9001C>G p.L3001V (on ENST00000409039; = p.L2940V on NM_207437.3) | Missense Mutation (SNP) | VAF 109/521 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68998923; called by muse, mutect2, varscan2
- DNAH3 | c.9703C>T p.L3235F | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54509716; called by muse, mutect2, varscan2
- DNAH5 | c.12328G>A p.D4110N | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54217754; called by muse, mutect2, varscan2
- DOCK3 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs768565725, COSV56515200; called by muse, mutect2, varscan2
- DOCK6 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 151/586 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs1224524375, COSV53911710; called by muse, mutect2, varscan2
- DSC1 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs1237560581, COSV99938243; called by muse, mutect2, varscan2
- DSG1 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 101/366 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs372724391, COSV99935466; called by muse, mutect2, varscan2
- DVL2 | c.1801dup p.A601Gfs*21 | Frame Shift Ins (INS) | VAF 164/661 reads (25%) | catalogued as rs745455027; called by mutect2, varscan2
- EFS | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 156/693 reads (23%) | catalogued as rs927690975; called by muse, mutect2, varscan2
- FAM184B | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as rs558493843; called by muse, mutect2, varscan2
- FAM222A | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 183/750 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62723017; called by muse, mutect2, varscan2
- FAM90A26 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753603880; called by muse, mutect2, varscan2
- FAN1 | c.2872C>T p.L958F | Missense Mutation (SNP) | VAF 151/634 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs147984615; called by muse, mutect2, varscan2
- FCAMR | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 91/462 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs889695963; called by muse, mutect2, varscan2
- FCAR | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 152/592 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs773603335, COSV100629206, COSV62028187; called by muse, mutect2, varscan2
- FLG | c.8540C>T p.S2847L | Missense Mutation (SNP) | VAF 163/1443 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs754300448, COSV64242164; called by muse, mutect2, varscan2
- FOXN4 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 86/415 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs992896013; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 88/521 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GGN | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 179/781 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.033); catalogued as COSV53057699; called by muse, mutect2, varscan2
- GHR | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867392523, COSV50109830, COSV50135382; called by muse, mutect2, varscan2
- GIGYF2 | c.3697G>A p.G1233R | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1430168685, COSV65249417; called by muse, mutect2, varscan2
- GIGYF2 | c.3698G>A p.G1233E | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV65249746; called by muse, mutect2, varscan2
- GJA4 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 169/702 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.755); catalogued as COSV60726308; called by muse, mutect2, varscan2
- GK2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 219/533 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as COSV62626410; called by muse, mutect2, varscan2
- GLIPR1L1 | c.691C>A p.P231T (on ENST00000378695 / NM_001304964.2; = p.P222T on NM_152779.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.559); catalogued as rs750054991; called by mutect2, varscan2
- GNS | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 182/717 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs964775472; called by muse, mutect2, varscan2
- GP6 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 148/584 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1408985833; called by muse, mutect2
- GRIN2A | c.3172C>T p.H1058Y | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs988036800; called by muse, mutect2, varscan2
- GRIN2B | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 148/672 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV74206909; called by muse, mutect2, varscan2
- H1-4 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 105/693 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs906666018; called by muse, mutect2, varscan2
- HCRTR2 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs866820748, COSV63797066; called by muse, varscan2
- HGFAC | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 302/866 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746660806; called by muse, mutect2, varscan2
- HOOK2 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 158/764 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs139576838; called by muse, mutect2, varscan2
- HR | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 58/1085 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1425295433; called by muse, mutect2
- IGLV3-9 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs766619498; called by muse, mutect2, varscan2
- ITPKB | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 148/661 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs374593738; called by muse, mutect2, varscan2
- KASH5 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 92/382 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs369117540; called by muse, mutect2
- KIAA0586 | c.824C>T p.S275F (on ENST00000619416 / NM_001244190.2; = p.S290F on NM_014749.5) | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs186378072; called by muse, mutect2, varscan2
- KIF1C | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 177/687 reads (26%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.968); catalogued as rs1194761969; called by muse, mutect2, varscan2
- KLHL18 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1263126449; called by muse, mutect2, varscan2
- KPRP | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 169/704 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1303958363, COSV64222826; called by muse, mutect2, varscan2
- KRTAP25-1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1181392432; called by muse, mutect2, varscan2
- LALBA | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV56395811; called by muse, mutect2, varscan2
- LAMC1 | c.2600G>A p.G867E | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362420474; called by muse, mutect2, varscan2
- LARS2 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as COSV104376780; called by muse, mutect2, varscan2
- LCOR | c.4058C>T p.P1353L | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99617221; called by muse, mutect2, varscan2
- LCT | c.5507G>A p.R1836Q | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.282); catalogued as rs1392489897, COSV99738976; called by muse, mutect2, varscan2
- LPAR1 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 31/242 reads (13%) | catalogued as COSV62692283; called by muse, mutect2, varscan2
- LRCH2 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100406899, COSV57758368; called by muse, mutect2, varscan2
- LRRC32 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 179/785 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1225186070; called by muse, mutect2, varscan2
- LRRC4C | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53419039, COSV53424818; called by muse, mutect2, varscan2
- LRRC53 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.301); catalogued as rs866975601, COSV53953358; called by muse, mutect2, varscan2
- LRRK2 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54142603; called by muse, mutect2, varscan2
- LTA | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 230/1754 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs530890501; called by muse, mutect2, varscan2
- MALRD1 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs200935166; called by muse, mutect2, varscan2
- MC3R | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 167/653 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.673); catalogued as COSV54764667; called by muse, mutect2, varscan2
- MGAM2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs527596455; called by muse, mutect2, varscan2
- MOV10L1 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs775263348, COSV53174093; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- MYOCD | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748342025, COSV58509104; called by muse, mutect2, varscan2
- NAA25 | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as rs1268158376; called by muse, mutect2, varscan2
- NBEA | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 60/192 reads (31%) | catalogued as COSV59781919; called by muse, mutect2, varscan2
- NCKAP5 | c.3128G>A p.R1043K | Missense Mutation (SNP) | VAF 158/612 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV100489953; called by muse, mutect2, varscan2
- NFKB2 | c.1971C>T p.L657= | Splice Region (SNP) | VAF 112/488 reads (23%) | catalogued as rs1235585705; called by muse, mutect2, varscan2
- NLRP7 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 212/906 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV100051584; called by muse, mutect2, varscan2
- NOSTRIN | c.856G>A p.E286K (on ENST00000317647 / NM_001039724.4; = p.E208K on NM_052946.3) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV58320708; called by muse, mutect2, varscan2
- NPAS4 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 110/453 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100215327, COSV60649273; called by muse, mutect2, varscan2
- NPHP1 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as COSV57210694; called by muse, mutect2, varscan2
- NR2C1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 120/462 reads (26%) | catalogued as COSV58012279; called by muse, mutect2, varscan2
- OFD1 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as COSV60794194; called by muse, mutect2, varscan2
- OR4K1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99579123; called by muse, mutect2, varscan2
- OR4K17 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59648646; called by muse, mutect2, varscan2
- OR51M1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60785304; called by muse, mutect2, varscan2
- OSBP | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 35/144 reads (24%) | catalogued as COSV55661436; called by muse, mutect2, varscan2
- OTUD4 | c.1138C>T p.R380* (on ENST00000447906 / NM_001366057.1; = p.R315* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 75/217 reads (35%) | catalogued as rs777026222; called by muse, mutect2, varscan2
- P2RY2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 150/626 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773254428; called by muse, mutect2, varscan2
- PAH | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as CM1511451, CM930561; called by muse, mutect2, varscan2
- PAPPA2 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62806610; called by muse, mutect2, varscan2
- PCDH15 | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs867154687, COSV57284690, COSV57325635; called by muse, mutect2, varscan2
- PCDHB7 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs782752563; called by muse, mutect2, varscan2
- PCDHGA4 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 119/528 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs769198002, COSV53913227; called by muse, mutect2, varscan2
- PCNT | c.3805G>A p.G1269S | Missense Mutation (SNP) | VAF 129/613 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.53); catalogued as rs760175380; called by muse, mutect2, varscan2
- PIAS2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61343909; called by muse, mutect2, varscan2
- PIBF1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 55/294 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58325615; called by muse, mutect2, varscan2
- PITPNC1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55450192; called by muse, mutect2, varscan2
- PKP2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 87/377 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as rs759377911, COSV50752588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNLIPRP3 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293183373, COSV65049741; called by muse, mutect2, varscan2
- POLK | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146120634; called by muse, mutect2, varscan2
- POM121C | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 157/714 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99992545; called by muse, mutect2, varscan2
- POTEF | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 112/618 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62540840; called by muse, mutect2, varscan2
- PRAG1 | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 129/526 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs763452274; called by muse, varscan2
- PRDM15 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 134/528 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768225892, COSV54156183; called by muse, mutect2, varscan2
- PTGR1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as rs962907646; called by muse, mutect2, varscan2
- PTPN23 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 130/530 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99650355; called by muse, mutect2, varscan2
- PTPRM | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59841972; called by muse, mutect2, varscan2
- RAG2 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs139419162, COSV57556829; called by muse, mutect2, varscan2
- RANBP2 | c.7880C>T p.P2627L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51699744; called by muse, mutect2, varscan2
- RELN | c.4435G>A p.D1479N | Missense Mutation (SNP) | VAF 245/427 reads (57%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.955); catalogued as rs781311212, COSV58991833; called by muse, mutect2, varscan2
- RGPD4 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100736323; called by muse, mutect2, varscan2
- RGS11 | c.955G>A p.D319N (on ENST00000397770 / NM_183337.3; = p.D298N on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/389 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs750161923; called by muse, mutect2, varscan2
- RNF26 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 160/715 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1263904973; called by muse, mutect2, varscan2
- SCIN | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as rs952085736, COSV51693199; called by muse, mutect2, varscan2
- SCN3A | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs754710772; called by muse, mutect2, varscan2
- SCN8A | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 47/205 reads (23%) | catalogued as rs1555225532, COSV61976795; called by muse, mutect2, varscan2
- SERPINB12 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs948500841; called by muse, mutect2, varscan2
- SFTPD | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV64852900; called by muse, mutect2, varscan2
- SHROOM3 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 382/994 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV56023036; called by muse, mutect2, varscan2
- SIGLEC11 | c.936G>A p.W312* | Nonsense Mutation (SNP) | VAF 97/521 reads (19%) | catalogued as rs113344458; called by muse, mutect2, varscan2
- SIM1 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 124/589 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs776861600, COSV53497878, COSV99492589; called by muse, varscan2
- SLC20A1 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1050491233, COSV55610375; called by muse, mutect2, varscan2
- SLC34A2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs746078874, COSV65940773; called by muse, mutect2, varscan2
- SLC34A2 | c.1809G>A p.W603* | Nonsense Mutation (SNP) | VAF 193/906 reads (21%) | catalogued as rs780348999; called by muse, mutect2, varscan2
- SLC46A3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308441470, COSV57179961; called by muse, mutect2, varscan2
- SOGA3 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 196/726 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1414332345, COSV64107558; called by muse, mutect2, varscan2
- SPINDOC | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 132/523 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.318); catalogued as COSV99588654; called by muse, mutect2, varscan2
- SPOCK3 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs377199025; called by muse, mutect2, varscan2
- SPTA1 | c.5190G>A p.E1730= | Splice Region (SNP) | VAF 3/18 reads (17%) | catalogued as rs867887614, COSV100935761, COSV63748741; called by muse, mutect2, varscan2
- SS18 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99294385; called by muse, mutect2, varscan2
- SSC4D | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 48/1176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1407015077; called by muse, mutect2
- STAU1 | c.662C>T p.S221L (on ENST00000371856 / NM_001319135.1; = p.S140L on NM_004602.3) | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.219); catalogued as COSV61458910; called by muse, mutect2, varscan2
- STK31 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750306514, COSV63453990; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59131757; called by muse, mutect2, varscan2
- STX11 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs747149545; called by muse, mutect2, varscan2
- STX17 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1020039496; called by muse, varscan2
- STYXL2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 161/603 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1165783461, COSV99608485; called by muse, mutect2, varscan2
- TACC2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 161/686 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1411146175, COSV57751738; called by muse, mutect2, varscan2
- TAS1R2 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 157/712 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1489917240, COSV100946330; called by muse, mutect2, varscan2
- TBC1D13 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 147/512 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV56355924; called by muse, mutect2, varscan2
- TBC1D2B | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 142/502 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746609944, COSV56041464; called by muse, mutect2, varscan2
- TCIM | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370896349; called by muse, mutect2, varscan2
- TEX50 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60960957; called by muse, mutect2, varscan2
- TIAM1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 140/549 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1235285275, COSV54542593; called by muse, mutect2, varscan2
- TMEM237 | c.382C>T p.R128W (on ENST00000409883 / NM_001044385.3; = p.R120W on NM_152388.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs370790275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNK2 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 174/720 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.936); catalogued as rs564644836; called by muse, mutect2, varscan2
- TOP1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV63695828; called by muse, mutect2, varscan2
- TTC28 | c.6407C>T p.S2136L | Missense Mutation (SNP) | VAF 113/539 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101195181; called by muse, mutect2, varscan2
- TTN | c.25400G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV59876824; called by muse, mutect2, varscan2
- TTN | c.14207C>T p.S4736L (on ENST00000591111; = p.S3809L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | PolyPhen benign (0.306); catalogued as COSV59901220; called by muse, mutect2, varscan2
- TTN | c.6890G>A p.G2297E (on ENST00000591111; = p.G2251E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV59874453; called by muse, mutect2, varscan2
- TYW3 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 153/641 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866381122, COSV61717287; called by muse, mutect2, varscan2
- UBXN4 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147972423, COSV55638751; called by muse, mutect2, varscan2
- UNC13C | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs902686676; called by muse, mutect2, varscan2
- WDR35 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs376071012; called by muse, mutect2, varscan2
- WTIP | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 162/656 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1443092152; called by muse, mutect2, varscan2
- ZC3H12A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 137/555 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV66104027, COSV66104098; called by muse, mutect2, varscan2
- ZC3H3 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 150/716 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs373816160; called by muse, varscan2
- ZDHHC7 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 149/560 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV58213708; called by muse, mutect2, varscan2
- ZFP1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs1360540580; called by muse, mutect2, varscan2
- ZFP91 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV60158798; called by muse, mutect2, varscan2
- ZFP92 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 255/518 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58598117; called by muse, mutect2, varscan2
- ZNF236 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 163/621 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750101274; called by muse, mutect2, varscan2
- ZNF436 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs866523417; called by muse, mutect2, varscan2
- ZNF469 | c.6529G>A p.D2177N (on ENST00000437464; = p.D2205N on NM_001367624.2) | Missense Mutation (SNP) | VAF 147/602 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1322998747; called by muse, mutect2, varscan2
- ZNF536 | c.3386C>T p.S1129F | Missense Mutation (SNP) | VAF 143/593 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV62827319; called by muse, mutect2, varscan2
- ZNF804A | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100168869; called by muse, mutect2, varscan2
- ZNF93 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59375083; called by mutect2, varscan2
- ABHD17A | c.584C>T p.P195L (on ENST00000292577 / NM_001130111.2; = p.P246L on NM_031213.4) | Missense Mutation (SNP) | VAF 46/932 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ACSM5 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 114/468 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY7 | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 143/559 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AFP | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- AGAP3 | c.973C>T p.P325S (on ENST00000622464; = p.P361S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 843/1253 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ALPK2 | c.3652C>T p.L1218F | Missense Mutation (SNP) | VAF 125/472 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- AMPD1 | c.1313_1322dup p.K441Nfs*19 | Frame Shift Ins (INS) | VAF 26/122 reads (21%) | called by mutect2, varscan2
- ANKFN1 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.1375A>T p.K459* | Nonsense Mutation (SNP) | VAF 137/607 reads (23%) | called by muse, mutect2, varscan2
- ANTXRL | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 127/547 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- AP3B2 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 116/425 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- AP4B1 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ARHGAP24 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ARL6 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 95/352 reads (27%) | called by muse, mutect2, varscan2
- ASAH2 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 113/439 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C10orf62 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 151/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C20orf203 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- C2orf16 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2orf16 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CABP5 | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 145/587 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CACNA1C | c.2389G>A p.G797R | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CASP10 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 73/379 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC6 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CENPE | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CEP164 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CEP170 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, varscan2
- CFAP43 | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CHADL | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 178/667 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CKAP2L | c.1662T>A p.F554L | Missense Mutation (SNP) | VAF 148/563 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLIP1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 116/539 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- COL1A1 | c.4205G>A p.G1402D | Missense Mutation (SNP) | VAF 134/562 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL20A1 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 130/658 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- CRIP1 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 155/580 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CRYBG2 | c.3152C>T p.P1051L | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUL4A | c.1678G>A p.G560R (on ENST00000375440 / NM_001008895.4; = p.G460R on NM_003589.3) | Missense Mutation (SNP) | VAF 99/453 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DAOA | c.223A>T p.R75W | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DCAF5 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 160/650 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- DENND6A | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 110/488 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.114); called by muse, varscan2
- DGAT2 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 118/496 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DNAH2 | c.8962G>A p.G2988R | Missense Mutation (SNP) | VAF 109/427 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH5 | c.8118G>A p.M2706I | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 160/225 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DSP | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 254/606 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DTL | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DYNC2H1 | c.5612C>T p.T1871I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EFCAB8 | c.3100G>A p.D1034N | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ELAVL4 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EQTN | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EXOC2 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 139/362 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC2 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 139/362 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FA2H | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM189A1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 129/612 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, varscan2
- FAM71A | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 175/712 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM83C | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 184/740 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO46 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 214/869 reads (25%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FBXO46 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 215/866 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FCER2 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 145/647 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FCHO1 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 144/593 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCN2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 126/582 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FMNL1 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 120/561 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, varscan2
- FNDC1 | c.3995G>A p.G1332E | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FRMPD2 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- GEMIN2 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPAM | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GPATCH8 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- GPR137 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 159/551 reads (29%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR20 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 246/980 reads (25%) | called by muse, mutect2
- GPR20 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 243/936 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GRB10 | c.1736G>A p.G579E (on ENST00000398812; = p.G533E on NM_001001549.3) | Missense Mutation (SNP) | VAF 274/689 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRHL1 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 115/456 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCFC1 | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 218/435 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR9 | c.1177A>G p.T393A | Missense Mutation (SNP) | VAF 161/643 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- HECTD4 | c.3112C>T p.P1038S | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- HROB | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 137/515 reads (27%) | called by muse, mutect2, varscan2
- HTR4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 50/232 reads (22%) | PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- IFNA8 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IL17RA | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 152/594 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IQCF2 | c.105A>C p.K35N | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JKAMP | c.368G>A p.S123N (on ENST00000554271 / NM_001284201.1; = p.S109N on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JPH2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 226/863 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIAA0825 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KL | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 179/751 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- KLB | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 126/319 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KLF10 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 123/506 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRCH2 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- LRIT1 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 139/667 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1 | c.6059G>A p.G2020E | Missense Mutation (SNP) | VAF 82/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP2 | c.8006G>A p.G2669D | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP3 | c.1796C>G p.P599R | Missense Mutation (SNP) | VAF 177/825 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- LRP8 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 127/575 reads (22%) | called by muse, mutect2, varscan2
- LUZP1 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 118/525 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MALRD1 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MAP4K3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- MCTP1 | c.1828T>A p.L610I | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MPRIP | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 168/656 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MTERF4 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 90/376 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- MUC2 | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 137/584 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC7 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 345/992 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- MYO1B | c.29T>A p.L10H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MYO7B | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 126/571 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MYO7B | c.4816G>A p.E1606K | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NOS1AP | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 135/586 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN3 | c.1759G>A p.E587K (on ENST00000335750 / NM_001330195.2; = p.E214K on NM_004796.6) | Missense Mutation (SNP) | VAF 149/573 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- PAIP2B | c.353T>A p.I118N | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- PCDHB11 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHB5 | c.2225G>A p.G742E | Missense Mutation (SNP) | VAF 168/742 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- PFKFB3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 97/535 reads (18%) | PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PKHD1L1 | c.4210G>A p.G1404R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLAGL2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 168/600 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PLB1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 125/512 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PLCB4 | c.3071G>A p.W1024* | Nonsense Mutation (SNP) | VAF 49/270 reads (18%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PLEKHN1 | c.758G>A p.W253* (on ENST00000379409; = p.W213* on NM_001160184.2) | Nonsense Mutation (SNP) | VAF 116/470 reads (25%) | called by muse, mutect2, varscan2
- PLPP4 | c.310A>T p.I104L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PMIS2 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 124/548 reads (23%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PPP3CB | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF18 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 109/1007 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRDM9 | c.609C>T p.L203= | Splice Region (SNP) | VAF 85/295 reads (29%) | called by muse, mutect2, varscan2
- PRKACG | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 157/568 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PRKCQ | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RAB2B | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 60/256 reads (23%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- RAB43 | c.502_504delinsTA p.N168* | Frame Shift Del (DEL) | VAF 111/896 reads (12%) | called by pindel, varscan2*
- RAPGEFL1 | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 139/523 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RINT1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 251/403 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RP1L1 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 108/494 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RUSC2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 193/696 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 152/625 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SCART1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 149/653 reads (23%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SLC26A7 | c.1293G>A p.W431* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 121/490 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9B1 | c.466T>G p.L156V | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPATA31A1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 171/838 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- STAB2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- STAB2 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- STARD9 | c.5261_5265dup p.L1756Mfs*3 | Frame Shift Ins (INS) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- STK31 | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.3392G>A p.G1131E | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SZT2 | c.5120G>A p.G1707E (on ENST00000634258 / NM_001365999.1; = p.G1650E on NM_015284.4) | Missense Mutation (SNP) | VAF 73/423 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TAMALIN | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBL1XR1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TCP1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- TECPR2 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TECRL | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECRL | c.139A>T p.R47* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- TEX13B | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 175/385 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- THRB | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- THSD4 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 139/495 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TIMELESS | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TLN2 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 165/670 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TMEM219 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 136/569 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM63B | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 121/981 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNS4 | c.631C>G p.H211D | Missense Mutation (SNP) | VAF 144/642 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TPH1 | c.32A>T p.H11L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM35 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TRIM55 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 153/629 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TRIM56 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 188/908 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TTL | c.515T>C p.F172S | Missense Mutation (SNP) | VAF 93/330 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TTN | c.12041C>T p.P4014L (on ENST00000591111; = p.P3968L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- UTP25 | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- VIPR1 | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 117/477 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWDE | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- WDFY4 | c.3637G>T p.D1213Y | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR87 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WWP1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- XDH | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XYLT1 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 147/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YWHAG | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 324/817 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ZBTB8A | c.233T>A p.V78D | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZC3H12C | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZNF223 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF28 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF417 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ZNF439 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- ZNF460 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 98/418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF541 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 90/445 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ZNF677 | c.715A>G p.K239E | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.26); called by muse, mutect2
- ZNF99 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ABCA8 | c.1311G>A p.L437= | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- ABCC2 | c.1584C>T p.L528= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- ACACA | c.6081C>T p.T2027= | Silent (SNP) | VAF 55/232 reads (24%) | called by muse, mutect2, varscan2
- ACP5 | c.807G>A p.R269= | Silent (SNP) | VAF 106/585 reads (18%) | catalogued as COSV54535631; called by muse, mutect2, varscan2
- ACTL9 | c.1128G>A p.R376= | Silent (SNP) | VAF 167/646 reads (26%) | catalogued as rs1354488069, COSV61005593; called by muse, mutect2, varscan2
- ADGRA2 | c.3957G>A p.A1319= | Silent (SNP) | VAF 170/651 reads (26%) | catalogued as COSV55105143; called by muse, mutect2, varscan2
- AIPL1 | c.1089C>T p.S363= | Silent (SNP) | VAF 200/789 reads (25%) | catalogued as rs1297009308, COSV51508620; called by muse, mutect2, varscan2
- AK1 | c.84C>T p.I28= | Silent (SNP) | VAF 133/526 reads (25%) | catalogued as rs375333097, COSV56344797; called by muse, mutect2, varscan2
- AKAP11 | c.2652A>T p.V884= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- ARAP2 | c.912C>T p.F304= | Silent (SNP) | VAF 67/165 reads (41%) | called by muse, mutect2, varscan2
- ARL14EPL | c.339G>A p.P113= | Silent (SNP) | VAF 108/498 reads (22%) | catalogued as rs75839405; called by muse, mutect2, varscan2
- ATAD2 | c.84C>T p.F28= | Silent (SNP) | VAF 163/647 reads (25%) | catalogued as rs138728114; called by muse, mutect2, varscan2
- ATF7IP | c.2511C>T p.S837= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs1319426475, COSV99661529; called by muse, mutect2, varscan2
- ATP10D | c.2424G>A p.V808= | Silent (SNP) | VAF 55/320 reads (17%) | catalogued as rs989345452; called by muse, mutect2, varscan2
- ATP13A1 | c.324C>T p.C108= | Silent (SNP) | VAF 137/627 reads (22%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2910C>T p.F970= (on ENST00000545399 / NM_001256214.2; = p.F957= on NM_152296.5) | Silent (SNP) | VAF 148/590 reads (25%) | catalogued as rs782381226; called by muse, mutect2, varscan2
- ATP2C2 | c.978C>T p.I326= | Silent (SNP) | VAF 102/426 reads (24%) | catalogued as rs546891646; called by muse, mutect2, varscan2
- BMS1 | c.759C>T p.H253= | Silent (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- BRINP1 | c.243G>A p.R81= | Silent (SNP) | VAF 37/288 reads (13%) | catalogued as COSV56296082; called by muse, mutect2, varscan2
- C2CD3 | c.2079C>T p.P693= | Silent (SNP) | VAF 77/309 reads (25%) | called by muse, mutect2, varscan2
- C2orf16 | c.858G>A p.K286= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- C2orf16 | c.2319G>A p.A773= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs766660061, COSV71613990; called by muse, mutect2, varscan2
- C3orf56 | c.433C>T p.L145= | Silent (SNP) | VAF 73/374 reads (20%) | called by muse, mutect2, varscan2
- CACNA1E | c.2103C>T p.I701= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs368547834; called by muse, mutect2, varscan2
- CALR | c.840C>T p.I280= | Silent (SNP) | VAF 103/450 reads (23%) | catalogued as rs760708514; called by muse, mutect2, varscan2
- CAMSAP1 | c.2874C>T p.L958= | Silent (SNP) | VAF 185/606 reads (31%) | catalogued as rs138126670; called by muse, mutect2, varscan2
- CASKIN1 | c.4182G>A p.E1394= | Silent (SNP) | VAF 114/458 reads (25%) | catalogued as rs752599521; called by muse, mutect2, varscan2
- CCDC80 | c.2430G>T p.L810= | Silent (SNP) | VAF 80/373 reads (21%) | called by muse, mutect2, varscan2
- CD81 | c.558C>T p.F186= | Silent (SNP) | VAF 107/428 reads (25%) | called by muse, mutect2, varscan2
- CDH20 | c.990C>T p.F330= | Silent (SNP) | VAF 56/277 reads (20%) | catalogued as rs1167520609; called by muse, mutect2, varscan2
- CEACAM16 | c.963C>T p.I321= | Silent (SNP) | VAF 114/485 reads (24%) | catalogued as rs748040042, COSV69188041; called by muse, mutect2, varscan2
- CELF4 | c.123G>A p.G41= | Silent (SNP) | VAF 189/788 reads (24%) | catalogued as rs776644983, COSV58452684; called by muse, mutect2, varscan2
- CFAP58 | c.369G>A p.L123= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV57211599; called by muse, mutect2, varscan2
- CHD3 | c.429C>T p.G143= | Silent (SNP) | VAF 62/385 reads (16%) | catalogued as rs953259544; called by muse, mutect2, varscan2
- CHD3 | c.430C>T p.L144= | Silent (SNP) | VAF 61/389 reads (16%) | called by muse, mutect2, varscan2
- CHMP6 | c.72G>A p.K24= | Silent (SNP) | VAF 101/467 reads (22%) | catalogued as rs767798208; called by muse, mutect2, varscan2
- CKLF | c.378C>T p.A126= (on ENST00000264001 / NM_016951.4; = p.A41= on NM_016326.3) | Silent (SNP) | VAF 109/452 reads (24%) | catalogued as COSV99862482; called by muse, mutect2, varscan2
- CLYBL | c.789C>T p.A263= | Silent (SNP) | VAF 78/236 reads (33%) | called by muse, mutect2, varscan2
- COCH | c.1167G>A p.R389= (on ENST00000216361 / NM_001347720.1; = p.R324= on NM_004086.3) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1193729124, COSV53551875; called by muse, mutect2, varscan2
- CPAMD8 | c.3141C>T p.I1047= (on ENST00000651564; = p.I1000= on NM_015692.5) | Silent (SNP) | VAF 187/781 reads (24%) | catalogued as rs267605340, COSV71595901; called by muse, mutect2, varscan2
- CPM | c.81G>A p.G27= | Silent (SNP) | VAF 120/486 reads (25%) | called by muse, mutect2, varscan2
- CSAD | c.297C>T p.P99= (on ENST00000444623 / NM_001244705.2; = p.P126= on NM_015989.5) | Silent (SNP) | VAF 122/485 reads (25%) | called by muse, mutect2, varscan2
- CST9 | c.474G>A p.G158= | Silent (SNP) | VAF 89/339 reads (26%) | catalogued as COSV65402938; called by muse, mutect2, varscan2
- CST9 | c.84C>T p.A28= | Silent (SNP) | VAF 104/451 reads (23%) | called by muse, mutect2, varscan2
- CUL9 | c.2985C>T p.F995= | Silent (SNP) | VAF 210/1393 reads (15%) | called by muse, mutect2, varscan2
- CYP4F11 | c.1236C>T p.R412= | Silent (SNP) | VAF 86/410 reads (21%) | catalogued as rs140718122, COSV56125462, COSV56130652; called by muse, mutect2, varscan2
- DBN1 | c.198C>T p.G66= | Silent (SNP) | VAF 175/692 reads (25%) | called by muse, mutect2, varscan2
- DDRGK1 | c.816C>T p.T272= | Silent (SNP) | VAF 131/581 reads (23%) | called by muse, mutect2, varscan2
- DLC1 | c.3994C>T p.L1332= (on ENST00000276297 / NM_001348081.2; = p.L895= on NM_006094.5) | Silent (SNP) | VAF 73/336 reads (22%) | called by muse, mutect2, varscan2
- DOCK4 | c.516G>A p.P172= | Silent (SNP) | VAF 164/232 reads (71%) | catalogued as rs374420579; called by muse, mutect2, varscan2
- DPYD | c.2518C>T p.L840= | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- EMILIN3 | c.1884C>T p.A628= | Silent (SNP) | VAF 167/713 reads (23%) | called by muse, mutect2, varscan2
- EPB41L4B | c.1614C>T p.S538= | Silent (SNP) | VAF 95/415 reads (23%) | called by muse, mutect2, varscan2
- EPHB1 | c.1389C>T p.I463= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as rs1416925667; called by muse, mutect2, varscan2
- EPPK1 | c.3981C>T p.Y1327= | Silent (SNP) | VAF 194/780 reads (25%) | called by muse, mutect2, varscan2
- ERICH3 | c.2181G>A p.K727= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1164432284, COSV100445357; called by muse, mutect2, varscan2
- FAM111B | c.1956C>T p.S652= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- FAM53B | c.753C>T p.A251= | Silent (SNP) | VAF 143/580 reads (25%) | catalogued as rs776484455; called by muse, mutect2, varscan2
- FAN1 | c.2871C>T p.G957= | Silent (SNP) | VAF 146/599 reads (24%) | called by muse, varscan2
- FARS2 | c.1050G>A p.Q350= | Silent (SNP) | VAF 36/281 reads (13%) | called by muse, mutect2, varscan2
- FGF21 | c.474C>T p.P158= | Silent (SNP) | VAF 183/720 reads (25%) | catalogued as rs768888677, COSV99711567; called by muse, mutect2, varscan2
- FKBP10 | c.111C>T p.A37= | Silent (SNP) | VAF 124/631 reads (20%) | called by muse, mutect2, varscan2
- FRYL | c.657C>T p.V219= | Silent (SNP) | VAF 105/340 reads (31%) | catalogued as COSV51941903; called by muse, mutect2, varscan2
- FSHR | c.1746C>T p.F582= | Silent (SNP) | VAF 75/347 reads (22%) | catalogued as COSV100436333; called by muse, mutect2, varscan2
- GABRG1 | c.450C>T p.F150= | Silent (SNP) | VAF 133/348 reads (38%) | catalogued as COSV54949354; called by muse, mutect2, varscan2
- GALNS | c.843C>T p.T281= | Silent (SNP) | VAF 143/581 reads (25%) | catalogued as COSV99243530; called by muse, mutect2, varscan2
- GALNT6 | c.903C>T p.I301= | Silent (SNP) | VAF 124/477 reads (26%) | catalogued as rs150719035; called by muse, mutect2, varscan2
- GBP5 | c.1659A>G p.A553= | Silent (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- GCOM1 | c.195G>A p.R65= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as rs1454131664, COSV51088193; called by muse, mutect2, varscan2
- GDPD5 | c.1050G>A p.K350= | Silent (SNP) | VAF 182/779 reads (23%) | called by muse, mutect2, varscan2
- GPR179 | c.4296G>A p.E1432= (on ENST00000621958; = p.E1431= on NM_001004334.4) | Silent (SNP) | VAF 187/734 reads (25%) | called by muse, mutect2, varscan2
- GPRASP2 | c.693T>C p.S231= | Silent (SNP) | VAF 139/293 reads (47%) | called by muse, mutect2, varscan2
- GRM8 | c.1575G>A p.R525= | Silent (SNP) | VAF 259/464 reads (56%) | catalogued as COSV58846241; called by muse, mutect2, varscan2
- GRM8 | c.699G>A p.E233= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs1256487314; called by muse, mutect2, varscan2
- GUCA1B | c.216C>T p.T72= | Silent (SNP) | VAF 294/547 reads (54%) | called by muse, mutect2, varscan2
- GUCY2C | c.234G>A p.V78= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- HAL | c.1800C>T p.I600= | Silent (SNP) | VAF 67/357 reads (19%) | catalogued as rs137860207; called by muse, mutect2, varscan2
- HAPLN4 | c.399C>T p.V133= | Silent (SNP) | VAF 155/603 reads (26%) | called by muse, mutect2, varscan2
- HCFC1 | c.3567C>T p.A1189= | Silent (SNP) | VAF 213/433 reads (49%) | catalogued as rs782488868; called by muse, mutect2, varscan2
- HECTD4 | c.3111C>T p.F1037= | Silent (SNP) | VAF 54/220 reads (25%) | called by muse, mutect2, varscan2
- HNF4G | c.108C>T p.F36= (on ENST00000354370 / NM_001330561.2; = p.F83= on NM_004133.5) | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as COSV100584749; called by muse, mutect2, varscan2
- HNRNPCL2 | c.162C>T p.F54= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs1310106678; called by muse, mutect2, varscan2
- IGF1R | c.1884C>T p.I628= | Silent (SNP) | VAF 110/427 reads (26%) | catalogued as rs753390403, COSV51407050, COSV99148846; called by muse, mutect2, varscan2
- IGHV3-73 | c.27C>T p.F9= | Silent (SNP) | VAF 38/208 reads (18%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.198C>T p.P66= | Silent (SNP) | VAF 78/325 reads (24%) | catalogued as rs1192488775; called by muse, mutect2, varscan2
- IGSF1 | c.3519C>T p.F1173= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100812399, COSV63839221; called by muse, mutect2, varscan2
- IL11 | c.439C>T p.L147= | Silent (SNP) | VAF 121/542 reads (22%) | called by muse, mutect2, varscan2
- INPP5D | c.576C>T p.L192= (on ENST00000445964 / NM_001017915.3; = p.L191= on NM_005541.5) | Silent (SNP) | VAF 122/592 reads (21%) | catalogued as rs1291281370, COSV64036976; called by muse, mutect2, varscan2
- INSYN2A | c.1200G>A p.T400= | Silent (SNP) | VAF 77/298 reads (26%) | catalogued as rs745985733, COSV54729281, COSV54762092; called by muse, mutect2, varscan2
- KIAA0586 | c.825C>T p.S275= (on ENST00000619416 / NM_001244190.2; = p.S290= on NM_014749.5) | Silent (SNP) | VAF 74/305 reads (24%) | called by muse, mutect2, varscan2
- KIDINS220 | c.5053C>T p.L1685= | Silent (SNP) | VAF 63/307 reads (21%) | called by muse, mutect2, varscan2
- KIF14 | c.3525C>T p.P1175= | Silent (SNP) | VAF 108/394 reads (27%) | catalogued as rs548095378, COSV66262626; called by muse, mutect2, varscan2
- KIF26B | c.4035G>A p.E1345= | Silent (SNP) | VAF 189/832 reads (23%) | called by muse, mutect2, varscan2
- KIF26B | c.5406G>A p.R1802= | Silent (SNP) | VAF 189/962 reads (20%) | called by muse, mutect2, varscan2
- KIF2B | c.336C>T p.A112= | Silent (SNP) | VAF 139/607 reads (23%) | called by muse, mutect2, varscan2
- KLB | c.1326G>A p.Q442= | Silent (SNP) | VAF 126/320 reads (39%) | called by muse, mutect2, varscan2
- KLHDC7A | c.2253G>A p.R751= | Silent (SNP) | VAF 118/453 reads (26%) | called by muse, mutect2, varscan2
- LARGE2 | c.726G>A p.K242= | Silent (SNP) | VAF 166/658 reads (25%) | called by muse, mutect2, varscan2
- LONP1 | c.888C>T p.I296= | Silent (SNP) | VAF 126/480 reads (26%) | catalogued as rs759362983; called by muse, varscan2
- LPA | c.5626C>T p.L1876= | Silent (SNP) | VAF 49/226 reads (22%) | called by muse, mutect2, varscan2
- LPIN2 | c.1344A>G p.G448= | Silent (SNP) | VAF 157/598 reads (26%) | called by muse, mutect2, varscan2
- LRIT1 | c.1437G>A p.G479= | Silent (SNP) | VAF 142/671 reads (21%) | called by muse, mutect2, varscan2
- LRP3 | c.1797C>T p.P599= | Silent (SNP) | VAF 178/832 reads (21%) | catalogued as rs767401051; called by muse, mutect2, varscan2
- LRSAM1 | c.486C>T p.I162= | Silent (SNP) | VAF 112/431 reads (26%) | called by muse, mutect2, varscan2
- LUZP2 | c.972G>A p.V324= | Silent (SNP) | VAF 49/219 reads (22%) | catalogued as COSV61204648; called by muse, varscan2
- MARCO | c.1275G>A p.R425= | Silent (SNP) | VAF 108/527 reads (20%) | catalogued as rs1202205753; called by muse, mutect2, varscan2
- MBL2 | c.746G>A p.*249= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100906295; called by muse, mutect2, varscan2
- MGAM | c.549C>T p.F183= | Silent (SNP) | VAF 108/215 reads (50%) | called by muse, mutect2, varscan2
- MITF | c.1092A>C p.A364= (on ENST00000448226 / NM_006722.3; = p.A264= on NM_000248.4) | Silent (SNP) | VAF 46/206 reads (22%) | called by muse, mutect2, varscan2
- MORN4 | c.114C>T p.T38= | Silent (SNP) | VAF 104/419 reads (25%) | called by muse, mutect2, varscan2
- MTMR11 | c.1362C>T p.F454= (on ENST00000439741 / NM_001145862.2; = p.F382= on NM_181873.3) | Silent (SNP) | VAF 92/408 reads (23%) | catalogued as rs1364104448, COSV54966703; called by muse, mutect2, varscan2
- MUC21 | c.1017C>T p.S339= | Silent (SNP) | VAF 887/1752 reads (51%) | called by muse, mutect2, varscan2
- MUC22 | c.2085C>T p.I695= | Silent (SNP) | VAF 202/1328 reads (15%) | called by muse, mutect2
- MYLK | c.3729C>T p.F1243= | Silent (SNP) | VAF 130/479 reads (27%) | catalogued as COSV60611723; called by muse, mutect2, varscan2
- MYMK | c.378C>T p.I126= | Silent (SNP) | VAF 115/481 reads (24%) | called by muse, mutect2, varscan2
- MYO16 | c.483C>A p.I161= | Silent (SNP) | VAF 41/210 reads (20%) | called by muse, mutect2, varscan2
- NALCN | c.4899A>G p.Q1633= | Silent (SNP) | VAF 83/388 reads (21%) | called by muse, mutect2, varscan2
- NALCN | c.4002G>A p.K1334= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs748417807, COSV51945763, COSV51960706; called by muse, mutect2, varscan2
- NBL1 | c.54C>T p.A18= | Silent (SNP) | VAF 155/682 reads (23%) | catalogued as rs929008061; called by muse, mutect2, varscan2
- NDUFA6 | c.189C>T p.V63= | Silent (SNP) | VAF 100/401 reads (25%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.99C>T p.V33= | Silent (SNP) | VAF 119/452 reads (26%) | called by muse, mutect2, varscan2
- NEFM | c.1290C>T p.I430= | Silent (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- NEK10 | c.1734T>C p.I578= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- NEU4 | c.9C>T p.V3= (on ENST00000391969 / NM_001167602.3; = p.V15= on NM_080741.4) | Silent (SNP) | VAF 117/582 reads (20%) | catalogued as rs1170606470; called by muse, mutect2, varscan2
- NEUROG1 | c.493C>T p.L165= | Silent (SNP) | VAF 180/768 reads (23%) | catalogued as rs371962821; called by muse, mutect2
- NFATC2IP | c.753C>T p.V251= | Silent (SNP) | VAF 137/662 reads (21%) | called by muse, mutect2, varscan2
- NHSL1 | c.210C>T p.S70= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs1222093587; called by muse, mutect2, varscan2
- NOC3L | c.177G>A p.K59= | Silent (SNP) | VAF 50/226 reads (22%) | called by muse, mutect2, varscan2
- NPFFR2 | c.666C>T p.I222= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- NPY2R | c.636G>A p.K212= | Silent (SNP) | VAF 195/510 reads (38%) | catalogued as rs762500063; called by muse, mutect2, varscan2
- NSD1 | c.4902G>A p.R1634= | Silent (SNP) | VAF 145/587 reads (25%) | catalogued as rs765422367; called by muse, mutect2, varscan2
- NUDT16L1 | c.480C>T p.F160= | Silent (SNP) | VAF 188/704 reads (27%) | catalogued as rs143151090, COSV99273896; called by muse, mutect2, varscan2
- OBSCN | c.5661C>T p.T1887= | Silent (SNP) | VAF 104/469 reads (22%) | called by muse, mutect2, varscan2
- OR10A6 | c.753C>T p.F251= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100564322; called by muse, mutect2, varscan2
- OR10H1 | c.84C>T p.F28= | Silent (SNP) | VAF 188/687 reads (27%) | catalogued as COSV58472244; called by muse, mutect2, varscan2
- OR1G1 | c.9G>A p.G3= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV61030208; called by muse, mutect2, varscan2
- OR1M1 | c.549C>T p.P183= | Silent (SNP) | VAF 141/569 reads (25%) | catalogued as COSV70036974; called by muse, mutect2, varscan2
- OR2A5 | c.111C>T p.T37= | Silent (SNP) | VAF 251/525 reads (48%) | called by muse, mutect2, varscan2
- OR2M7 | c.90G>A p.L30= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100522612; called by muse, varscan2
- OR2T12 | c.528C>T p.F176= | Silent (SNP) | VAF 168/675 reads (25%) | called by muse, mutect2, varscan2
- OR2W1 | c.843C>T p.I281= | Silent (SNP) | VAF 88/147 reads (60%) | called by muse, mutect2, varscan2
- OR51G2 | c.624C>T p.I208= | Silent (SNP) | VAF 60/264 reads (23%) | catalogued as rs371119617; called by muse, mutect2, varscan2
- PLEKHA4 | c.360C>T p.T120= | Silent (SNP) | VAF 88/398 reads (22%) | catalogued as rs757929474; called by muse, mutect2, varscan2
- PNLIPRP3 | c.738G>A p.G246= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as rs1366593237, COSV65049029, COSV65049170; called by muse, varscan2
- POLK | c.381C>T p.P127= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1176517352; called by muse, mutect2, varscan2
- PPP1R15A | c.1857C>T p.L619= | Silent (SNP) | VAF 184/722 reads (25%) | catalogued as COSV99565790; called by muse, mutect2, varscan2
- PRAMEF4 | c.213G>A p.L71= | Silent (SNP) | VAF 198/700 reads (28%) | catalogued as COSV99340115; called by muse, mutect2, varscan2
- PRR5 | c.541C>T p.L181= (on ENST00000336985 / NM_181333.4; = p.L172= on NM_015366.4) | Silent (SNP) | VAF 130/565 reads (23%) | catalogued as COSV99134229; called by muse, mutect2, varscan2
- PSPC1 | c.1461C>T p.T487= | Silent (SNP) | VAF 93/442 reads (21%) | called by muse, mutect2, varscan2
- PTPN13 | c.2361G>A p.K787= | Silent (SNP) | VAF 58/289 reads (20%) | called by muse, mutect2, varscan2
- RAD54L2 | c.3621C>T p.A1207= | Silent (SNP) | VAF 161/733 reads (22%) | catalogued as rs747548309; called by muse, mutect2, varscan2
- RALGAPA1 | c.3576C>T p.I1192= | Silent (SNP) | VAF 52/210 reads (25%) | called by muse, mutect2, varscan2
- RASGRF2 | c.1227G>A p.R409= | Silent (SNP) | VAF 51/243 reads (21%) | catalogued as COSV99429714; called by muse, mutect2, varscan2
- RBM27 | c.642C>T p.S214= | Silent (SNP) | VAF 68/290 reads (23%) | called by muse, mutect2, varscan2
- RBM47 | c.465C>T p.I155= | Silent (SNP) | VAF 145/857 reads (17%) | catalogued as rs1027590780, COSV55933150; called by muse, mutect2, varscan2
- RELB | c.282C>T p.T94= | Silent (SNP) | VAF 165/761 reads (22%) | catalogued as rs1455204009; called by muse, mutect2, varscan2
- RGS9 | c.1266A>G p.E422= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as rs1487473490; called by muse, mutect2, varscan2
- RNF32 | c.672C>T p.F224= | Silent (SNP) | VAF 99/266 reads (37%) | called by muse, mutect2, varscan2
- RPTOR | c.3756C>T p.I1252= | Silent (SNP) | VAF 162/624 reads (26%) | catalogued as rs750566631; called by muse, mutect2, varscan2
- RYK | c.345G>A p.A115= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs762957307, COSV56060822; called by muse, mutect2, varscan2
- SCN11A | c.3535C>T p.L1179= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- SCN3B | c.492C>T p.I164= | Silent (SNP) | VAF 69/288 reads (24%) | catalogued as COSV54800237; called by muse, mutect2, varscan2
- SCUBE1 | c.1179G>A p.R393= | Silent (SNP) | VAF 122/500 reads (24%) | called by muse, mutect2, varscan2
- SEC14L5 | c.2085C>T p.S695= | Silent (SNP) | VAF 103/488 reads (21%) | called by muse, mutect2, varscan2
- SGMS1 | c.438C>T p.F146= | Silent (SNP) | VAF 80/389 reads (21%) | catalogued as rs773593436, COSV62369479; called by muse, mutect2, varscan2
- SI | c.3861A>C p.G1287= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2
- SIGLEC5 | c.462G>A p.L154= | Silent (SNP) | VAF 55/352 reads (16%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.1302C>T p.F434= | Silent (SNP) | VAF 117/464 reads (25%) | called by muse, mutect2, varscan2
- SIM1 | c.1566C>T p.I522= | Silent (SNP) | VAF 77/289 reads (27%) | catalogued as COSV53497958; called by muse, mutect2, varscan2
- SIRPB1 | c.1170C>T p.I390= | Silent (SNP) | VAF 72/310 reads (23%) | called by muse, mutect2, varscan2
- SLC12A5 | c.2505C>T p.S835= (on ENST00000454036 / NM_001134771.2; = p.S812= on NM_020708.5) | Silent (SNP) | VAF 137/639 reads (21%) | called by muse, mutect2, varscan2
- SLC16A9 | c.1377C>T p.T459= | Silent (SNP) | VAF 77/312 reads (25%) | catalogued as COSV68101154; called by muse, mutect2, varscan2
- SLC16A9 | c.690G>A p.K230= | Silent (SNP) | VAF 76/310 reads (25%) | called by muse, mutect2, varscan2
- SLC22A25 | c.1350C>T p.T450= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- SLC22A7 | c.975G>A p.G325= (on ENST00000372585 / NM_153320.2; = p.G323= on NM_006672.3) | Silent (SNP) | VAF 82/613 reads (13%) | called by muse, mutect2, varscan2
- SLC34A1 | c.123C>T p.I41= | Silent (SNP) | VAF 149/489 reads (30%) | catalogued as rs759907707; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC43A3 | c.1164C>T p.L388= | Silent (SNP) | VAF 149/688 reads (22%) | called by muse, mutect2, varscan2
- SLC45A4 | c.2136C>T p.F712= (on ENST00000517878 / NM_001286646.2; = p.F661= on NM_001080431.2) | Silent (SNP) | VAF 165/760 reads (22%) | catalogued as COSV99198744; called by muse, mutect2
- SLIT2 | c.2409C>T p.L803= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1370165220; called by muse, mutect2, varscan2
- SMG1 | c.6423C>T p.L2141= | Silent (SNP) | VAF 48/228 reads (21%) | called by muse, mutect2, varscan2
- SMOC2 | c.1039C>T p.L347= (on ENST00000356284 / NM_001166412.2; = p.L358= on NM_022138.3) | Silent (SNP) | VAF 90/427 reads (21%) | catalogued as COSV62433930; called by muse, mutect2, varscan2
- SORL1 | c.2388C>T p.D796= | Silent (SNP) | VAF 90/453 reads (20%) | called by muse, mutect2, varscan2
- SOX9 | c.1344C>T p.S448= | Silent (SNP) | VAF 161/680 reads (24%) | catalogued as COSV55424094; called by muse, mutect2, varscan2
- SPTBN1 | c.1896C>T p.A632= | Silent (SNP) | VAF 140/625 reads (22%) | called by muse, mutect2, varscan2
- SPTBN4 | c.4146G>A p.R1382= | Silent (SNP) | VAF 144/641 reads (22%) | catalogued as rs1420822382; called by muse, mutect2, varscan2
- SS18L1 | c.615C>T p.S205= | Silent (SNP) | VAF 157/680 reads (23%) | called by muse, mutect2, varscan2
- SUCLA2 | c.1284G>A p.R428= (on ENST00000643023; = p.R407= on NM_003850.3) | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV66222571; called by muse, mutect2, varscan2
- SYT4 | c.1224C>T p.I408= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1039506688, COSV54897958; called by muse, mutect2, varscan2
- SYTL3 | c.642C>T p.L214= | Silent (SNP) | VAF 132/549 reads (24%) | catalogued as rs1474411246; called by muse, mutect2, varscan2
- SZT2 | c.8667C>T p.A2889= (on ENST00000634258 / NM_001365999.1; = p.A2832= on NM_015284.4) | Silent (SNP) | VAF 111/538 reads (21%) | catalogued as rs1240938356; called by muse, mutect2, varscan2
- TAS1R2 | c.1485T>C p.C495= | Silent (SNP) | VAF 92/355 reads (26%) | called by muse, mutect2, varscan2
- TBC1D14 | c.1924C>T p.L642= | Silent (SNP) | VAF 368/830 reads (44%) | called by muse, mutect2, varscan2
- TBC1D22A | c.399C>T p.P133= | Silent (SNP) | VAF 128/634 reads (20%) | called by muse, mutect2, varscan2
- TBC1D24 | c.285C>T p.F95= | Silent (SNP) | VAF 170/727 reads (23%) | catalogued as rs774354974; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TCHH | c.5697G>A p.G1899= | Silent (SNP) | VAF 184/689 reads (27%) | called by muse, mutect2
- THSD1 | c.2208G>A p.R736= | Silent (SNP) | VAF 132/530 reads (25%) | catalogued as COSV51628856; called by muse, mutect2, varscan2
- TMCO4 | c.1162C>T p.L388= | Silent (SNP) | VAF 128/531 reads (24%) | called by muse, mutect2, varscan2
- TMCO4 | c.1161C>T p.I387= | Silent (SNP) | VAF 135/543 reads (25%) | catalogued as COSV53874515; called by muse, mutect2, varscan2
- TRAF1 | c.612C>T p.L204= | Silent (SNP) | VAF 110/504 reads (22%) | called by muse, mutect2, varscan2
- TRAV3 | c.315C>T p.S105= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as rs778585299; called by muse, mutect2, varscan2
- TRIM64C | c.66C>T p.F22= | Silent (SNP) | VAF 77/362 reads (21%) | called by muse, mutect2, varscan2
- TRIO | c.7425C>A p.P2475= | Silent (SNP) | VAF 180/778 reads (23%) | catalogued as rs761657839, COSV59990062; called by muse, mutect2, varscan2
- TTBK2 | c.3039C>T p.P1013= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs55919340; called by muse, mutect2, varscan2
- TTC38 | c.453T>C p.A151= | Silent (SNP) | VAF 118/461 reads (26%) | called by muse, mutect2, varscan2
- TYW3 | c.69G>A p.K23= | Silent (SNP) | VAF 151/636 reads (24%) | catalogued as COSV61718418; called by muse, mutect2, varscan2
- UFSP1 | c.78C>T p.H26= | Silent (SNP) | VAF 193/1054 reads (18%) | catalogued as rs369098327; called by muse, mutect2, varscan2
- UNC80 | c.2700C>T p.I900= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs995706379, COSV55899628; called by muse, mutect2, varscan2
- VARS2 | c.717C>T p.S239= | Silent (SNP) | VAF 723/1290 reads (56%) | called by muse, mutect2, varscan2
- VSIG10 | c.798C>T p.I266= | Silent (SNP) | VAF 116/577 reads (20%) | catalogued as rs371816744; called by muse, mutect2, varscan2
- WDFY3 | c.7089C>T p.G2363= | Silent (SNP) | VAF 271/677 reads (40%) | called by muse, mutect2, varscan2
- XDH | c.2530C>T p.L844= | Silent (SNP) | VAF 76/342 reads (22%) | catalogued as COSV65148852; called by muse, mutect2, varscan2
- XKR4 | c.309G>A p.E103= | Silent (SNP) | VAF 86/429 reads (20%) | called by muse, mutect2, varscan2
- XPC | c.2058C>T p.S686= | Silent (SNP) | VAF 106/535 reads (20%) | catalogued as rs755498328; called by muse, mutect2, varscan2
- ZFHX4 | c.795C>T p.F265= | Silent (SNP) | VAF 54/305 reads (18%) | catalogued as rs934470343, COSV50526666; called by muse, mutect2, varscan2
- ZNF142 | c.3492C>T p.V1164= (on ENST00000411696 / NM_001379660.1; = p.V964= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 143/685 reads (21%) | called by muse, mutect2, varscan2
- ZNF316 | c.1734C>T p.F578= | Silent (SNP) | VAF 377/956 reads (39%) | called by muse, mutect2, varscan2
- ZNF483 | c.2001A>G p.E667= | Silent (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- ZNF648 | c.1500G>A p.G500= | Silent (SNP) | VAF 146/645 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.156C>T p.H52= | Silent (SNP) | VAF 182/800 reads (23%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.157C>T p.L53= | Silent (SNP) | VAF 181/803 reads (23%) | called by muse, mutect2, varscan2
- ABCA1 | c.720+2507G>A | Intron (SNP) | VAF 87/272 reads (32%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-12009C>T | Intron (SNP) | VAF 69/356 reads (19%) | called by muse, mutect2, varscan2
- AC136777.2 | chr8:261108 G>A | 5'Flank (SNP) | VAF 33/129 reads (26%) | catalogued as rs148287124; called by muse, mutect2, varscan2
- AL163540.1 | n.40G>A | RNA (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- ARHGEF4 | chr2:130916331 C>T | 5'Flank (SNP) | VAF 148/638 reads (23%) | called by muse, mutect2, varscan2
- CCDC57 | c.2242-5534G>A | Intron (SNP) | VAF 157/667 reads (24%) | catalogued as rs758136129; called by muse, mutect2, varscan2
- DPF3 | c.871+2961G>A | Intron (SNP) | VAF 107/509 reads (21%) | called by muse, mutect2, varscan2
- EIF3L | c.-75G>A | 5'UTR (SNP) | VAF 233/817 reads (29%) | catalogued as COSV99316372; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2463+1157C>T | Intron (SNP) | VAF 79/351 reads (23%) | catalogued as rs747821271, COSV58553655; called by muse, mutect2, varscan2
- INTS11 | c.429+399G>A | Intron (SNP) | VAF 112/465 reads (24%) | catalogued as rs891723583; called by muse, mutect2, varscan2
- KANSL2 | c.-10+113T>C | Intron (SNP) | VAF 107/493 reads (22%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+34995C>T | Intron (SNP) | VAF 23/99 reads (23%) | catalogued as rs1264919298; called by muse, mutect2, varscan2
- LINC02881 | n.373+93C>T | Intron (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- MRO | c.-47G>A | 5'UTR (SNP) | VAF 105/453 reads (23%) | catalogued as COSV99839181; called by muse, mutect2, varscan2
- MTUS1 | c.2449+1910C>T | Intron (SNP) | VAF 26/105 reads (25%) | catalogued as rs201990102; called by muse, mutect2, varscan2
- PITX2 | c.390+27G>A | Intron (SNP) | VAF 155/763 reads (20%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2991C>T | Intron (SNP) | VAF 21/92 reads (23%) | catalogued as rs1469819141, COSV100742681; called by muse, mutect2, varscan2
- SCAF8 | c.30+8063C>T | Intron (SNP) | VAF 68/309 reads (22%) | called by muse, mutect2, varscan2
- SERF2 | c.*158C>T | 3'UTR (SNP) | VAF 115/568 reads (20%) | called by muse, mutect2, varscan2
- SMARCA1 | c.*122A>G | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SYNPO2 | c.*5111C>T | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- TEPSIN | c.527-425G>A | Intron (SNP) | VAF 187/726 reads (26%) | called by muse, mutect2, varscan2
- TSHR | c.692+141T>A | Intron (SNP) | VAF 91/333 reads (27%) | catalogued as rs748384019; called by muse, mutect2, varscan2
- TSHR | c.692+142C>T | Intron (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
